Surgical pathology report (de-identified scan), TCGA case TCGA-66-2727, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2727-01A (Primary Tumor).

[page 1 of 3]
Material examined:

Left lower lobe and others

Clinical diagnosis and question

Left lower lobe bronchial carcinoma, suspected hepatic metastases (not confirmed).

REPORT ON FINDINGS**Macroscopy**

1) Left upper lobe: inflated, fixed preparation measuring 13 × 7 cm at the base and up to 18 cm in length. Pleura cloudy, lateral and dorsal adhesion residues and on the base, ventrobasal edge turned in a dorsal direction. Whitish yellow discoloration of the pleura in a laterobasal area up to 5 cm in size, with relatively clear demarcation at the edges. Bronchus displaced in the region of the B6/basal group branching, adjacent to two partially lesioned grayish black nodes up to 1.8 cm and on the ventral side to a parenchymal flap enclosed by a line of metal staple sutures 6 × 4 × 2 cm in size, apparently belonging to the lower lobe. Marker threads inserted in the middle of the central area of the row of clips there. Discontinuation of B8 and 9 in a nodular tumor with a largest extent of 4.2 cm extending from the central region to the periphery, with rather imprecise borders and with a markedly arched edge in places. Pale grey, vitreous tumor tissue, slate grey pigmentation towards the center, also irregularly circumscribed, eccentric cavity 8 mm in size. Extension of the tumor towards the pleura in the area of the point of contact with the parenchymal flap described. As far as could be detected no infiltration of the adjacent parenchymal flap. By the stretches of the root of B8 and 9 also large vascular branches let into the tumor and apparently destroyed in places. Slight twisting of the stretches of the root located in the tumor region of B10, this was otherwise clear as far as the periphery, like B6. Sections of B8 and 9 located peripherally of the tumor moderately widened, however, with whitish yellow material in the lumens in places. Pulmonary tissue densities, especially laterally in the tumor border area, with speckled, grayish brown section surfaces. A wedge-shaped area of induration of about the same size beneath the laterobasal pleural changes described. Normal parenchyma in segments 6 and 10.

2) S2 left upper lobe wedge: fragment of pulmonary tissue in filled, fixed condition, 1.9 × 1.5 cm at the base and up to 6 mm high, with hazy, cloudy pleura, eccentric pleura and parenchyma already incised, inclusion of pale grey area of induration about 1 cm in size extending as far as the base of the preparation with imprecise edges, in places more palpable than visible.

3) S1 left upper lobe wedge: already previously fixed, pale reddish tissue fragment 0.8 × 0.4 × 0.2 cm in size after an attempt at filling.

4) Lobar LN (item 12) left upper lobe: fragment of 1.1 cm with black-black pigment.

5) Hilar LN (item 10) left: two nodes of 1.3 and 1.9 cm with blackish pigment in places.

6) Pulmonary ligament lymph node (item 9) left: reddish fragment of 0.5 cm.

[page 2 of 3]
7) Paraesophageal LN (item 8) left: node 1.7 cm in size with a little black red pigment.

8) Subaortic LN (aortopulmonary window) (item 5): dark black red node, 0.9 cm in size, with pigment in places.

9) Subcarinal LN (item 7): black red node or partial node 1.3 cm in size, pigmented in places.

Examined

1) Rapid section residue (resection surface adjacent to parenchymal flap beneath the area of the staple suture line tangentially marked with thread), 3 other section of peripheral tumor with adjacent parenchymal flap (resection surface beneath the row of staple suture at this place marked in green, the point of removal of the rapid section sample marked in red), central tumor with stretch of root of B9 and central vascular branches of the basal group, 1 section each of periphery of the parenchymal tumor and the laterobasal induration area, central bronchial resection line and vascular displacement borders, nodes by the bronchial stump,

2) Laminated preparation,

3) - 9) Total material,

16 blocks, Elastic-van Gieson, PAS, diastase-PAS, iron

Microscopy

Description of the histological and cytological findings omitted for reasons of capacity.

EVALUATION

Bronchopulmonary carcinoma of the left lower pulmonary lobe extending from the center to the periphery, the center probably primary, histologically poorly or largely undifferentiated, large cell squamous cell epithelial carcinoma with keratinization. Tumor manifestation in segments 8 and 9, where there was surrounding and compression of the large pulmonary veins and incursion into and displacement of a branch of the pulmonary artery. Peripheral incursion of the carcinoma into the pleura of the inter-lobar cleft and minimal continuous progression into the jointly resected flap of pulmonary tissue from the upper lobe (clinically: lingula), where the removal point was free of tumor. Large area of parenchymal necrosis in the parts of the lower lobe behind that point in the nature of an infarction as a consequence of the disruption to blood flow caused by the tumor with massive accumulation of siderophages in the border region and accompanying fibrinous pleurisy that had already been smoldering for some time. Bronchus and vascular displacement borders free of tumor, also the altogether rather slight deposition of anthracotic pigment removed and lymph nodes showing reactive changes. No lymph nodes in sample 6), here pleural and mediastinal tissue with soft adhesive strands and chronic inflammation. In the small fragment of pulmonary tissue recorded under 3) a circumscribed focus of interstitial fibrosis or scarring with development of smooth muscle. In sample 2) a rather larger, striated or wedge-shaped parenchymal scar of the pulmonary parenchyma with atypical bronchiolo-alveolar or adenomatous cell proliferation at the edge. No or still no coincident bronchiolo-alveolar carcinoma.

[page 3 of 3]
Therefore in accordance with the tumor formula provided pT2 pN0 V1 R0, equivalent to stage IB.

Morphology:	8070/3
Topography:	C34.3
Grading:	3
Stage:	T2NoMxR0

Source: NCI Genomic Data Commons file 4edb74fc-fce6-42fd-9555-c097c441ab2e (TCGA-66-2727.97328404-08AC-4C35-B15C-79485D60C892.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).